Somatic mutation profile of tumor specimen TCGA-AG-3902-01A (aliquot TCGA-AG-3902-01A-01W-1073-09) from TCGA case TCGA-AG-3902, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.6 years (22,492 days).
Specimen TCGA-AG-3902-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58cde77c-b438-4641-9273-b5e68c7245a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3902-10A (Blood Derived Normal), aliquot TCGA-AG-3902-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef0a8fd0-c721-4f2f-90cd-738e2a28922d

The open-access MAF lists 141 somatic variants for this specimen: 107 protein-altering or splice-affecting, 34 silent.
By variant classification: Missense Mutation 85, Silent 34, Nonsense Mutation 14, Splice Site 3, Frame Shift Ins 2, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.2319G>A p.M773I | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV63976896; called by muse, mutect2, varscan2
- AHCTF1 | c.988G>A p.E330K (on ENST00000366508; = p.E304K on NM_015446.5) | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV58252782; called by muse, mutect2, varscan2
- AKAP11 | c.2173A>G p.I725V | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs772465835, COSV50298953; called by muse, mutect2, varscan2
- AMBN | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 67/294 reads (23%) | catalogued as COSV59827293; called by muse, mutect2, varscan2
- ANKS1B | c.3263T>A p.M1088K (on ENST00000547776 / NM_152788.4; = p.M254K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59122347; called by muse, mutect2, varscan2
- APC | c.1744-1G>A p.X582_splice | Splice Site (SNP) | VAF 18/81 reads (22%) | catalogued as COSV57352237, COSV57360238; called by mutect2, varscan2
- APC | c.3862G>T p.G1288* | Nonsense Mutation (SNP) | VAF 36/170 reads (21%) | catalogued as COSV57327258; called by muse, mutect2, varscan2
- ATP2B2 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs375973812; called by muse, mutect2, varscan2
- ATP8B1 | c.995A>T p.K332I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV99377351; called by muse, mutect2
- C5orf15 | c.788A>T p.Y263F | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51548758; called by muse, mutect2, varscan2
- CADM4 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1271716325, COSV55928245, COSV55929452; called by muse, mutect2
- CCPG1 | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60526651; called by muse, mutect2, varscan2
- CCR2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs368150580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPB | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); catalogued as rs765081320, COSV60148413; called by muse, mutect2, varscan2
- CENPF | c.5126T>C p.I1709T | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV65277023; called by muse, mutect2, varscan2
- CLSTN2 | c.2788G>C p.G930R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1238225325, COSV71723254; called by muse, mutect2, varscan2
- CMTR1 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65091014; called by muse, mutect2, varscan2
- CNKSR2 | c.2660G>T p.G887V | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54261688; called by muse, mutect2, varscan2
- COL5A2 | c.3297A>C p.Q1099H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV66411935; called by muse, mutect2, varscan2
- COPS5 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs143525514; called by muse, mutect2, varscan2
- DAB1 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV59732656; called by muse, mutect2, varscan2
- DAPK1 | c.1289T>A p.F430Y | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.931); catalogued as COSV63789740; called by muse, mutect2, varscan2
- DEFB126 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66694937; called by muse, mutect2, varscan2
- DENND1A | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs753283092, COSV65329270; called by muse, mutect2, varscan2
- DENND5B | c.3754C>T p.R1252* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs981331087, COSV60905681; called by muse, mutect2, varscan2
- DNAH8 | c.11845C>T p.R3949* | Nonsense Mutation (SNP) | VAF 51/193 reads (26%) | catalogued as rs150428096, COSV59485585; called by muse, mutect2, varscan2
- DPF2 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52890531; called by muse, mutect2, varscan2
- ELAVL2 | c.619A>C p.S207R | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV56366575; called by muse, mutect2, varscan2
- ELF3 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV62838350, COSV62839393; called by muse, mutect2, varscan2
- EML1 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV51744117, COSV51749097; called by muse, mutect2, varscan2
- FAT3 | c.5332C>G p.L1778V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV53146132; called by muse, mutect2, varscan2
- FLACC1 | c.921A>T p.E307D | Missense Mutation (SNP) | VAF 130/471 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.52); catalogued as COSV53785929; called by muse, mutect2, varscan2
- FZD6 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62470750, COSV62472034; called by muse, mutect2, varscan2
- GABRB2 | c.1015A>T p.K339* | Nonsense Mutation (SNP) | VAF 52/177 reads (29%) | catalogued as COSV50927075; called by muse, mutect2, varscan2
- GBP7 | c.782T>A p.F261Y | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54010797; called by muse, mutect2, varscan2
- GCC2 | c.1498A>G p.K500E | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV59178348; called by muse, mutect2, varscan2
- GPHN | c.1996A>C p.K666Q (on ENST00000315266 / NM_001377519.1; = p.K699Q on NM_020806.5) | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV59486939; called by muse, mutect2, varscan2
- GRIK3 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs754585903, COSV66135244; called by muse, mutect2, varscan2
- HAO2 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100378259, COSV58041140; called by muse, mutect2, varscan2
- HECTD1 | c.2426A>T p.E809V | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV67948024; called by muse, mutect2, varscan2
- HIVEP1 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV65103599; called by muse, mutect2, varscan2
- IPO8 | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV56243851; called by muse, mutect2, varscan2
- ITGB2 | c.2281C>T p.R761C (on ENST00000302347; = p.R737C on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs568682818, COSV100186163, COSV56611851; called by muse, mutect2, varscan2
- KCNS3 | c.604A>T p.M202L | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as COSV58408128; called by muse, mutect2, varscan2
- KNDC1 | c.2809G>A p.A937T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.74); catalogued as rs761999261, COSV58837462, COSV58842211; called by muse, mutect2, varscan2
- LANCL2 | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.356); catalogued as COSV54650879; called by muse, mutect2, varscan2
- LEO1 | c.67T>A p.S23T | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55176614; called by muse, mutect2, varscan2
- LZIC | c.87T>A p.D29E | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65890451; called by muse, mutect2, varscan2
- MCPH1 | c.1379A>T p.D460V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60916774; called by muse, mutect2, varscan2
- MUC17 | c.7606T>C p.S2536P | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV100073661; called by muse, mutect2, varscan2
- NFIC | c.739T>G p.F247V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV59414593; called by muse, mutect2, varscan2
- NRDC | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 69/267 reads (26%) | catalogued as COSV61406632; called by muse, mutect2, varscan2
- OGFRL1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs1322077668, COSV64972255; called by muse, mutect2, varscan2
- OR51A7 | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV63788682; called by muse, mutect2, varscan2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2, varscan2
- OSBPL6 | c.2651G>T p.R884L | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV51924356; called by muse, mutect2, varscan2
- PABPC5 | c.336C>A p.N112K | Missense Mutation (SNP) | VAF 82/125 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV57042155; called by muse, mutect2, varscan2
- PAX2 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs780688873, COSV62292144; called by muse, mutect2
- PCDH15 | c.5198A>G p.N1733S | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV57354954; called by muse, mutect2, varscan2
- PCDHA13 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as COSV56527176; called by muse, mutect2, varscan2
- PCDHA9 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV65329695; called by muse, mutect2, varscan2
- PHF14 | c.446C>G p.A149G | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.043); catalogued as COSV68856379; called by muse, mutect2, varscan2
- PKHD1L1 | c.10169C>T p.S3390L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs541350761, COSV65736783, COSV65747976; called by muse, mutect2, varscan2
- POU5F2 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs1266630516, COSV67939807; called by muse, mutect2, varscan2
- PRAMEF17 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1185627037; called by muse, mutect2, varscan2
- PREX2 | c.498A>T p.L166F | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395821618, COSV55761975, COSV55787067; called by muse, mutect2, varscan2
- PRLR | c.841G>C p.A281P | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV51497593, COSV51497993; called by muse, mutect2, varscan2
- PTGS1 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753219685, COSV56293178; called by muse, mutect2, varscan2
- RANBP9 | c.659A>C p.K220T | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV50583661; called by muse, mutect2, varscan2
- RAPGEF6 | c.200C>G p.S67* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV57250973, COSV99726986; called by muse, mutect2, varscan2
- RBM10 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 55/79 reads (70%) | catalogued as COSV61309256, COSV61309471; called by muse, mutect2, varscan2
- ROBO1 | c.4180G>C p.D1394H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV71396909; called by muse, mutect2, varscan2
- ROR1 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV64290272; called by muse, mutect2, varscan2
- SEPHS1 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV59259651; called by muse, mutect2, varscan2
- SERPINE3 | c.939A>C p.L313F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.567); catalogued as COSV68545659; called by muse, mutect2, varscan2
- SETX | c.4092A>C p.R1364S | Missense Mutation (SNP) | VAF 72/421 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV56389989; called by muse, mutect2, varscan2
- SLC25A18 | c.526A>C p.T176P | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as rs201336926, COSV53659248; called by muse, mutect2, varscan2
- SLC27A6 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs1465408468, COSV52480366, COSV52483062; called by muse, mutect2, varscan2
- SPATA31E1 | c.2393A>G p.K798R | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV57793646; called by muse, mutect2, varscan2
- SSX5 | c.280+1G>C p.X94_splice (on ENST00000347757 / NM_175723.1; = p.X135_splice on NM_021015.4) | Splice Site (SNP) | VAF 81/135 reads (60%) | catalogued as COSV100308776, COSV61254843; called by muse, mutect2, varscan2
- STX2 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV55435185; called by muse, mutect2, varscan2
- TAF6 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs751770909, COSV59840693; called by muse, mutect2, varscan2
- TCAF2 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV100633637; called by muse, mutect2, varscan2
- TENM3 | c.5831G>A p.R1944Q | Missense Mutation (SNP) | VAF 111/251 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV69314176; called by muse, mutect2, varscan2
- TG | c.1911G>A p.W637* | Nonsense Mutation (SNP) | VAF 48/226 reads (21%) | catalogued as rs745548824, CM141310, COSV55086566; called by muse, mutect2, varscan2
- THSD7B | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs764321163, COSV55714470; called by muse, mutect2, varscan2
- TLL2 | c.2596A>T p.M866L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63574192; called by muse, mutect2, varscan2
- TMEM132D | c.3169G>A p.D1057N | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.131); catalogued as rs761917469, COSV67159638, COSV67161366; called by muse, mutect2, varscan2
- TREM1 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV55149134; called by muse, mutect2, varscan2
- TRPS1 | c.3827dup p.N1276Kfs*5 (on ENST00000220888 / NM_001330599.2; = p.N1289Kfs*5 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 47/170 reads (28%) | catalogued as rs1401148397; called by mutect2, varscan2
- TTC29 | c.1213G>C p.A405P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57280387; called by muse, mutect2, varscan2
- UGT2B4 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 33/154 reads (21%) | catalogued as rs1426221113, COSV59318843; called by muse, mutect2, varscan2
- VPS36 | c.124_126del p.L42del | In Frame Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs763216059; called by pindel, varscan2
- VWA8 | c.636C>A p.Y212* | Nonsense Mutation (SNP) | VAF 69/344 reads (20%) | catalogued as COSV55700986; called by muse, mutect2, varscan2
- WNT2B | c.386G>C p.G129A (on ENST00000369684 / NM_024494.3; = p.G110A on NM_004185.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56675877; called by muse, mutect2, varscan2
- ZC2HC1C | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV53172962; called by muse, mutect2, varscan2
- ZFPM2 | c.2704C>T p.R902* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as rs753510236, COSV65874799; called by muse, mutect2, varscan2
- ZNF681 | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.438); catalogued as COSV101267483; called by muse, mutect2, varscan2
- ZNF71 | c.1101_1103del p.S368del | In Frame Del (DEL) | VAF 24/108 reads (22%) | catalogued as rs751724379; called by pindel, varscan2
- ZNF74 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs756807123, COSV62622340; called by muse, mutect2, varscan2
- ZSCAN20 | c.2733C>G p.S911R | Missense Mutation (SNP) | VAF 102/371 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV63683714; called by muse, mutect2, varscan2
- CT45A1 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 318/1930 reads (16%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CWC22 | c.121dup p.R41Pfs*3 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- PDCD2L | c.930_939del p.K311Ifs*2 | Frame Shift Del (DEL) | VAF 61/284 reads (21%) | called by mutect2, pindel, varscan2
- AASDH | c.423C>T p.L141= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs776194847, COSV52708479; called by muse, mutect2, varscan2
- AGO4 | c.2352G>C p.L784= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV64617931; called by muse, varscan2
- ALPK3 | c.3867C>A p.S1289= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV51936632; called by muse, mutect2, varscan2
- ANKMY2 | c.216A>C p.V72= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV61012207; called by muse, mutect2
- ANKRD30A | c.3912C>T p.N1304= (on ENST00000611781; = p.N1248= on NM_052997.2) | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs879093946, COSV64611340; called by muse, mutect2, varscan2
- ARHGEF28 | c.2541C>T p.V847= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as COSV55263690; called by muse, mutect2, varscan2
- ASNS | c.1419A>G p.G473= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV51554247; called by muse, mutect2, varscan2
- DSCAM | c.4668C>T p.C1556= | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as rs756384781, COSV68031803; called by muse, mutect2, varscan2
- ENKUR | c.717C>T p.H239= | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as rs755995761, COSV58634085; called by muse, mutect2, varscan2
- EXOC5 | c.1719T>G p.T573= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV61771666; called by muse, mutect2, varscan2
- GJA5 | c.261G>A p.T87= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs782281038, COSV54783900; called by muse, mutect2, varscan2
- GNB4 | c.235T>C p.L79= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV51710721; called by muse, mutect2, varscan2
- HDAC9 | c.1119G>A p.P373= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs771090434, COSV67779590; called by muse, mutect2, varscan2
- HNRNPA1 | c.147A>C p.P49= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52937839; called by muse, mutect2
- LRRC8C | c.565A>C p.R189= | Silent (SNP) | VAF 58/260 reads (22%) | catalogued as COSV64999818; called by muse, mutect2, varscan2
- MAP3K4 | c.714C>G p.V238= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as COSV62336177; called by muse, mutect2, varscan2
- MUC17 | c.7605T>A p.L2535= | Silent (SNP) | VAF 85/318 reads (27%) | catalogued as COSV100073656; called by muse, mutect2, varscan2
- NCL | c.453T>C p.D151= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV59546843; called by muse, mutect2, varscan2
- NMBR | c.1044G>A p.E348= | Silent (SNP) | VAF 56/218 reads (26%) | catalogued as COSV57802310; called by muse, mutect2, varscan2
- OR51B2 | c.132C>G p.L44= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV60917212, COSV60917357; called by muse, mutect2, varscan2
- PCDHB15 | c.1263C>A p.I421= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV50878790, COSV51157449; called by muse, mutect2, varscan2
- PCDHGA12 | c.186C>T p.R62= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99340524; called by muse, mutect2, varscan2
- PDCD2L | c.1032A>G p.E344= | Silent (SNP) | VAF 45/176 reads (26%) | catalogued as COSV55825932; called by muse, mutect2, varscan2
- PRL | c.333G>C p.L111= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as COSV100123262, COSV60592996; called by muse, mutect2
- RABGAP1 | c.756A>T p.I252= | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as COSV58060650; called by muse, mutect2, varscan2
- RB1CC1 | c.3294A>G p.E1098= | Silent (SNP) | VAF 70/134 reads (52%) | catalogued as COSV50259386; called by muse, mutect2, varscan2
- RBM14 | c.1077T>G p.R359= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV59559938; called by muse, mutect2, varscan2
- RYR3 | c.3303C>T p.V1101= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs752550511, COSV66801263, COSV66810148; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A31 | c.81C>T p.G27= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs768411036, COSV55420340; called by muse, mutect2, varscan2
- SLITRK3 | c.2892G>A p.P964= | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as rs781561672, COSV53850899, COSV99578396; called by muse, mutect2, varscan2
- SOAT2 | c.543G>A p.P181= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs151267658; called by muse, mutect2, varscan2
- TLN2 | c.5310C>T p.L1770= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs200255870; called by muse, mutect2, varscan2
- TOMM20L | c.315G>A p.E105= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as COSV53622005; called by muse, mutect2, varscan2
- WASHC5 | c.3177T>C p.N1059= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as COSV59198656; called by muse, mutect2, varscan2
